Somatic mutation profile of tumor specimen TCGA-B8-4621-01A (aliquot TCGA-B8-4621-01A-01D-1501-10) from TCGA case TCGA-B8-4621, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 63.5 years (23,176 days).
Specimen TCGA-B8-4621-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbe30044-836f-4a49-b46f-10c07cf2379c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B8-4621-10A (Blood Derived Normal), aliquot TCGA-B8-4621-10A-01D-1501-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0f9d15b-1d80-45cc-8401-745445a2b0b4

The open-access MAF lists 93 somatic variants for this specimen: 75 protein-altering or splice-affecting, 17 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 17, Frame Shift Del 11, Splice Site 3, Frame Shift Ins 2, Nonsense Mutation 2, In Frame Del 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA5 | c.1048A>C p.S350R | Missense Mutation (SNP) | VAF 205/474 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.111); catalogued as COSV67015631; called by muse, mutect2, varscan2
- ACSS2 | c.469A>G p.I157V | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV53622408; called by muse, mutect2, varscan2
- ACTR5 | c.1459C>A p.L487M | Missense Mutation (SNP) | VAF 64/294 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54759768; called by muse, mutect2, varscan2
- ADAM22 | c.2133C>A p.C711* | Nonsense Mutation (SNP) | VAF 109/440 reads (25%) | catalogued as COSV55969022; called by muse, mutect2, varscan2
- ADAMTS8 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57290993; called by muse, mutect2, varscan2
- AMPH | c.1426G>A p.A476T | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV57760706; called by muse, mutect2
- ATP13A2 | c.1239C>A p.H413Q | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1198645332, COSV58697959; called by muse, mutect2, varscan2
- BPTF | c.8794G>C p.D2932H | Missense Mutation (SNP) | VAF 90/221 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58830876; called by muse, mutect2, varscan2
- BRIP1 | c.713C>T p.T238I | Missense Mutation (SNP) | VAF 124/283 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs745955726, COSV51993659; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C17orf75 | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 53/111 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV56752182; called by muse, mutect2, varscan2
- CAT | c.1106A>G p.N369S | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148712764, COSV53810230; called by muse, mutect2, varscan2
- CCDC171 | c.1992G>C p.K664N | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV52633591; called by muse, mutect2, varscan2
- CDX1 | c.496C>A p.R166S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51567414, COSV99199299; called by muse, varscan2
- CLEC18B | c.1136A>T p.K379M | Missense Mutation (SNP) | VAF 24/373 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV60576403; called by muse, mutect2
- CNMD | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV65032282; called by muse, mutect2, varscan2
- CNR1 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.243); catalogued as rs868306589, COSV100759337; called by muse, mutect2
- CRAMP1 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 37/104 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV53521565; called by muse, mutect2, varscan2
- CREBBP | c.977C>T p.S326F | Missense Mutation (SNP) | VAF 143/666 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.706); catalogued as rs1311466278, COSV52113306; called by muse, mutect2, varscan2
- DNAH9 | c.10902C>A p.F3634L | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.346); catalogued as COSV52332724, COSV52371988; called by muse, mutect2, varscan2
- FAM166A | c.519C>A p.H173Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61115414, COSV61115643; called by muse, mutect2, varscan2
- FAT1 | c.4337T>A p.V1446E | Missense Mutation (SNP) | VAF 58/224 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71671791; called by muse, mutect2, varscan2
- HNRNPK | c.68C>A p.P23H | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57935158; called by muse, mutect2, varscan2
- HSD17B11 | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 64/229 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV64153855; called by muse, mutect2, varscan2
- HSP90B1 | c.2383-1G>A p.X795_splice | Splice Site (SNP) | VAF 110/518 reads (21%) | catalogued as COSV55353916; called by muse, mutect2
- HUWE1 | c.8701C>A p.Q2901K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV53333764; called by muse, mutect2, varscan2
- KCNT1 | c.1906G>A p.E636K (on ENST00000488444; = p.E655K on NM_020822.3) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs770039542, COSV53695173; called by muse, mutect2, varscan2
- LILRA6 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 16/144 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs201828111; called by muse, mutect2, varscan2
- MAGEA10 | c.783C>A p.H261Q | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as COSV54882698, COSV54884066; called by muse, mutect2, varscan2
- MAPK8IP1 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.04); catalogued as COSV53796515, COSV53798782; called by muse, mutect2, varscan2
- MIS18BP1 | c.2687C>T p.P896L | Missense Mutation (SNP) | VAF 60/202 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60368934; called by muse, mutect2, varscan2
- MTERF1 | c.182A>C p.K61T | Missense Mutation (SNP) | VAF 88/404 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV61097834; called by muse, mutect2, varscan2
- PACS2 | c.832C>T p.H278Y | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.642); catalogued as COSV57649705; called by muse, mutect2, varscan2
- PAQR5 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.034); catalogued as rs771060144, COSV61817325, COSV61818140; called by muse, mutect2, varscan2
- PCDHB8 | c.2261T>C p.V754A | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.216); catalogued as COSV50753673; called by muse, mutect2, varscan2
- PCNT | c.2230G>A p.E744K | Missense Mutation (SNP) | VAF 108/410 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs750981347, COSV64024772; called by muse, varscan2
- PGAP6 | c.1372A>T p.I458F | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.456); catalogued as COSV51737711; called by muse, mutect2, varscan2
- PKHD1 | c.2098T>C p.F700L | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV61859494; called by muse, mutect2, varscan2
- PNPLA8 | c.1216A>T p.I406F | Missense Mutation (SNP) | VAF 74/354 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV57551247, COSV99993959; called by muse, mutect2, varscan2
- PPRC1 | c.373G>A p.V125M | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.014); catalogued as rs775086501, COSV53382851; called by muse, mutect2, varscan2
- PRDM10 | c.1050G>C p.E350D | Missense Mutation (SNP) | VAF 56/199 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.994); catalogued as COSV58799085; called by muse, mutect2, varscan2
- PTEN | c.955_958del p.T319* | Frame Shift Del (DEL) | VAF 71/321 reads (22%) | catalogued as rs146650273; called by pindel, varscan2
- PTPDC1 | c.1960G>A p.V654I (on ENST00000375360 / NM_177995.3; = p.V706I on NM_152422.4) | Missense Mutation (SNP) | VAF 142/559 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.042); catalogued as COSV56621104; called by muse, mutect2, varscan2
- SCEL | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 158/526 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62992804; called by muse, mutect2, varscan2
- SLC28A1 | c.1890C>A p.F630L | Missense Mutation (SNP) | VAF 48/187 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV54476291; called by muse, mutect2, varscan2
- SLCO1B3 | c.750G>C p.K250N | Missense Mutation (SNP) | VAF 242/1268 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV53931751; called by muse, mutect2, varscan2
- SLITRK1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 48/203 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV65674066, COSV65677010; called by muse, mutect2, varscan2
- SLX4 | c.4439G>A p.G1480E | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); catalogued as COSV53560624; called by muse, mutect2, varscan2
- SYNJ1 | c.1876A>G p.I626V | Missense Mutation (SNP) | VAF 118/483 reads (24%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.992); catalogued as rs1174678552, COSV59143641; called by muse, mutect2, varscan2
- TAF1L | c.2104T>A p.Y702N | Missense Mutation (SNP) | VAF 127/444 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54256557; called by muse, mutect2, varscan2
- THSD7B | c.2404C>A p.P802T | Missense Mutation (SNP) | VAF 87/318 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV55651523; called by muse, mutect2, varscan2
- TINF2 | c.1253T>A p.F418Y | Missense Mutation (SNP) | VAF 59/200 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.04); catalogued as COSV57467978; called by muse, mutect2, varscan2
- TRAF7 | c.305C>G p.S102C | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.808); catalogued as COSV58212596; called by muse, mutect2, varscan2
- TRIM63 | c.606T>G p.S202R | Missense Mutation (SNP) | VAF 66/202 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.707); catalogued as COSV65327711; called by muse, mutect2, varscan2
- UBR1 | c.3209+1G>T p.X1070_splice | Splice Site (SNP) | VAF 167/612 reads (27%) | catalogued as COSV51925774; called by muse, mutect2, varscan2
- USP12 | c.147C>A p.Y49* | Nonsense Mutation (SNP) | VAF 59/192 reads (31%) | catalogued as COSV56654285; called by muse, mutect2, varscan2
- XDH | c.3038C>A p.P1013H | Missense Mutation (SNP) | VAF 135/424 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV65146715; called by muse, mutect2, varscan2
- ZDHHC1 | c.156G>T p.Q52H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62214504; called by muse, mutect2, varscan2
- ZNF184 | c.1053A>T p.E351D | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV53003083; called by muse, mutect2, varscan2
- ZNF195 | c.1771T>C p.S591P (on ENST00000399602 / NM_001130520.3; = p.S519P on NM_007152.5) | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); catalogued as COSV50001705; called by mutect2, varscan2
- ZNF608 | c.3197T>C p.V1066A | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.029); catalogued as COSV60435107; called by muse, mutect2, varscan2
- ADARB2 | c.2049del p.S683Rfs*27 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | called by mutect2, pindel, varscan2
- ATP2B4 | c.54_55del p.E19Rfs*26 | Frame Shift Del (DEL) | VAF 18/106 reads (17%) | called by mutect2, pindel
- CLCF1 | c.25_27del p.W9del | In Frame Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- CLCNKB | c.1024_1025insA p.P342Hfs*109 | Frame Shift Ins (INS) | VAF 36/109 reads (33%) | called by mutect2, pindel*, varscan2
- DHCR7 | c.369_382del p.G124Hfs*98 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by pindel, varscan2
- DHX35 | c.642dup p.K215Qfs*7 | Frame Shift Ins (INS) | VAF 210/517 reads (41%) | called by mutect2, pindel, varscan2
- GALK1 | c.760del p.S254Afs*10 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | called by mutect2, pindel, varscan2
- NKAIN2 | c.324del p.W108* | Frame Shift Del (DEL) | VAF 69/239 reads (29%) | called by mutect2, pindel, varscan2
- RAD52 | c.71del p.L24Yfs*20 | Frame Shift Del (DEL) | VAF 23/132 reads (17%) | called by mutect2, pindel, varscan2
- SLC25A36 | c.186del p.G63Dfs*6 | Frame Shift Del (DEL) | VAF 106/257 reads (41%) | called by mutect2, pindel, varscan2
- THSD4 | c.1207del p.V403Cfs*52 | Frame Shift Del (DEL) | VAF 41/185 reads (22%) | called by mutect2, pindel, varscan2
- TSC1 | c.2490_2502+16del p.X830_splice | Splice Site (DEL) | VAF 18/120 reads (15%) | called by mutect2, pindel, varscan2
- VRK2 | c.651del p.S218Afs*8 | Frame Shift Del (DEL) | VAF 75/265 reads (28%) | called by mutect2, pindel, varscan2
- XAB2 | c.1145_1150del p.V382_T384delinsA | In Frame Del (DEL) | VAF 8/62 reads (13%) | called by mutect2, pindel
- ZNF816 | c.299del p.D100Vfs*7 | Frame Shift Del (DEL) | VAF 48/207 reads (23%) | called by mutect2, pindel, varscan2
- ARHGAP17 | c.2265C>G p.P755= (on ENST00000289968 / NM_001006634.3; = p.P677= on NM_018054.6) | Silent (SNP) | VAF 77/171 reads (45%) | catalogued as COSV51504665; called by muse, mutect2, varscan2
- ASS1 | c.258C>A p.R86= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV61688382; called by muse, mutect2
- DHCR7 | c.363T>C p.F121= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as COSV100831776; called by muse, varscan2
- ERBIN | c.75T>C p.T25= | Silent (SNP) | VAF 112/342 reads (33%) | catalogued as COSV52310162; called by muse, varscan2
- GEMIN6 | c.402T>G p.T134= | Silent (SNP) | VAF 44/144 reads (31%) | catalogued as COSV56140060; called by muse, mutect2
- HK2 | c.1153C>T p.L385= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, varscan2
- HTR2B | c.1386T>C p.D462= | Silent (SNP) | VAF 96/355 reads (27%) | catalogued as COSV51448955; called by muse, mutect2, varscan2
- KCNK5 | c.414G>C p.G138= | Silent (SNP) | VAF 26/96 reads (27%) | catalogued as COSV63988507; called by muse, mutect2
- MANSC1 | c.927A>T p.A309= | Silent (SNP) | VAF 61/264 reads (23%) | catalogued as COSV67110611; called by muse, mutect2, varscan2
- MTOR | c.7578G>A p.E2526= | Silent (SNP) | VAF 74/269 reads (28%) | catalogued as rs1433711639, COSV63868186; called by muse, varscan2
- PCSK9 | c.1716C>T p.G572= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1199519345, COSV53761475; called by muse, mutect2
- PNMA1 | c.60T>C p.A20= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as COSV54092412; called by muse, mutect2, varscan2
- PRSS1 | c.132C>A p.G44= | Silent (SNP) | VAF 88/303 reads (29%) | catalogued as COSV61190236; called by muse, varscan2
- SOS1 | c.270C>A p.A90= | Silent (SNP) | VAF 103/325 reads (32%) | catalogued as COSV101216952, COSV67673644; called by muse, mutect2, varscan2
- TCEA2 | c.150G>C p.G50= | Silent (SNP) | VAF 58/108 reads (54%) | catalogued as COSV58657126, COSV58659383; called by muse, mutect2, varscan2
- VRK2 | c.721C>T p.L241= | Silent (SNP) | VAF 94/297 reads (32%) | catalogued as COSV60874487; called by muse, mutect2, varscan2
- ZNF595 | c.843G>A p.E281= | Silent (SNP) | VAF 22/56 reads (39%) | catalogued as COSV59547013; called by muse, mutect2, varscan2
- TNIP1 | c.-1C>T | 5'UTR (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100161186; called by muse, mutect2, varscan2
